Surgical pathology report (de-identified scan), TCGA case TCGA-A2-A0ST, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Walter Reed, specimen TCGA-A2-A0ST-01A (Primary Tumor).

[page 1 of 3]
1CD-0-5
Carcinoma, infiltrating ductal, NOS 8500/3
Site: breast, NOS C50.9 1/27/11

FOR OFFICIAL USE ONLY - PERSONAL DATA - PRIVACY ACT OF 1974

SURGICAL PATHOLOGY REPORT

Patient:
FMP/SSN:
DOB/Age/Sex:
Location:
Physician(s):

F Race: WHITE

Specimen #:

Taken: ()
Received: ()
Reported: ()

****AMENDED****

SPECIMEN:

A: RIGHT BREAST BIOPSY B: SENTINEL LYMPH NODE#1
C: SENTINEL LYMPH NODE#2

FINAL DIAGNOSIS:

A. BREAST, RIGHT, EXCISION:

- INFILTRATING DUCTAL CARCINOMA, POORLY DIFFERENTIATED (MODIFIED BLOOM-RICHARDSON GRADE 9: MITOSES=3, NUCLEAR PLEOMORPHISM=3, TUBULE FORMATION=3).
- TUMOR SIZE 2.0 CM.
- TUMOR IS LESS THAN 0.1 CM FROM ANTERIOR AND MEDIAL SURGICAL MARGINS.
- ASSOCIATED FINDINGS: FIBROCYSTIC CHANGES INCLUDING STROMAL SCLEROSIS AND MICROCYSTS.
- MICROCALCIFICATIONS IDENTIFIED, ASSOCIATED WITH BENIGN BREAST TISSUE.
- IMMUNOHISTOCHEMICAL STAINS FOR ESTROGEN AND PROGESTERONE AS FOLLOWS:
ESTROGEN RECEPTOR: NEGATIVE.
PROGESTERONE RECEPTOR: POSITIVE.
- HER2/NEU (FISH METHODOLOGY): NOT AMPLIFIED (1.3).

B. LYMPH NODE, SENTINEL LYMPH NODE#1, BIOPSY:

- ONE (1) LYMPH NODE POSITIVE FOR METASTATIC CARCINOMA ON H AND E AND IMMUNOHISTOLOGIC SECTIONS.
- TUMOR SEEN IS APPROXIMATELY 0.5 CM IN SIZE.

C. LYMPH NODE, SENTINEL LYMPH NODE#2, BIOPSY:

- ONE (1) LYMPH NODE POSITIVE FOR METASTATIC CARCINOMA ON H AND E AND IMMUNOHISTOLOGIC SECTIONS.
- TUMOR SEEN LESS THAN 0.1 CM IN SIZE.

COMMENT: This case is amended to reflect the review of immunohistochemical stains for estrogen and progesterone receptors and FISH for Her2/neu amplification. There is no change in diagnosis.

COMMENT

ge 1

Continued on Next Page

ONAL DATA - PRIVACY ACT OF 1974

[page 2 of 3]
SURGICAL PATHOLOGY REPORT

Patient:

Specimen #:

FINAL DIAGNOSIS (continued):

Case amended by to report results of HER2 analysis by immunohistochemistry (DAKO Hercep Test):

HER2/NEU PROTEIN OVEREXPRESSION: NEGATIVE (SCORE: 1+).

** Report Electronically Signed Out **

CLINICAL DIAGNOSIS AND HISTORY:

-year-old female with palpable mass on right breast with no ultrasound or mammographic correlation.

GROSS DESCRIPTION:

A. RIGHT BREAST BIOPSY received in formalin, labeled with the patient's name, designated "RIGHT BREAST EXCISIONAL BIOPSY" is a lumpectomy specimen measuring 10.2 x 7.0 x 3.0 cm in dimension. The specimen is composed largely of yellow, lobulated, glistening adipose tissue admixed with white fibrous areas. The specimen will be inked and oriented as follows: Black=deep, yellow=anterior, blue=medial, green=lateral, and red denotes superficial and inferior. The specimen is serially sectioned from superior to inferior revealing a fairly well-defined, grey/tan nodule, 1.5 cm in greatest dimension, abutting the anterior margin in the mid portion of the specimen. Immediately adjacent to this nodule is a 1.5 cm patch of indurated fibrous tissue involving the anterior and medial margins. The remaining tissue consists of an admixture of fibrous tissue (approximately 40%) and fat (approximately 60%). The fibrous tissue is variably indurated, particularly in the inferior half of the specimen. Sections of nodule and fibrous tissue are harvested for the CBCP protocol. Matching paraffin sections are as follows:

A1: Nodule.

A2: Indurated fibrous tissue adjacent to A1.

A3: Fibrous tissue 3.0 cm inferior to nodule.

A4: Fibrous tissue 6.0 cm inferior to nodule at the inferior margin.

The remainder of the specimen is serially sectioned and submitted from superior to inferior as follows:

A5-A12: Representative section from each level from superior to inferior.

[page 3 of 3]
SURGICAL PATHOLOGY REPORT

Patient:

Specimen #:

GROSS DESCRIPTION (continued):

A13-A14: Next lower level.
A15-A16: Next lower level.
A17-A18: Inferior most section.

B. SENTINEL LYMPH NODE#1 received in formalin, labeled with the patient's name, designated "SUPERIOR LYMPH NODE NUMBER ONE" is a 1.7 x 1.3 x 0.8 cm lymph node. A small portion of the node is harvested for the CBCP protocol. The remaining tissue is entirely submitted in cassette B1.

C. SENTINEL LYMPH NODE#2 received in formalin, labeled with the patient's name, designated "SENTINEL LYMPH NODE NUMBER TWO" is a 1.2 x 0.8 x 0.5 cm tan/brown lymph node. The tissue is entirely submitted in cassette C1.

Source: NCI Genomic Data Commons file e2da76ed-7e69-4a20-b767-1d2e6010819b (TCGA-A2-A0ST.1E8B978E-3D1B-46E8-80EE-3A11EE571CEC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).